Somatic mutation profile of tumor specimen TCGA-12-3653-01A (aliquot TCGA-12-3653-01A-01D-1495-08) from TCGA case TCGA-12-3653, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 34.3 years (12,529 days).
Specimen TCGA-12-3653-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d500956-2213-4dbd-8503-5bf74cc1458f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3653-10A (Blood Derived Normal), aliquot TCGA-12-3653-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b5d8814-b944-4f6a-8258-1c6a4c49ba10

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1169G>C p.G390A | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55958562, COSV55958958; called by muse, mutect2
- ACAP1 | c.1074C>A p.S358R | Missense Mutation (SNP) | VAF 96/148 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV50139169; called by muse, mutect2, varscan2
- ARL4D | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as COSV60721725; called by muse, mutect2, varscan2
- ATR | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs944345426, COSV63389722; called by muse, mutect2
- CDH9 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 130/242 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751593635, COSV50256584; called by muse, mutect2, varscan2
- CFAP57 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 120/234 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs142914910; called by muse, mutect2, varscan2
- CFAP74 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs150108692; called by muse, mutect2, varscan2
- COL28A1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs768670774, COSV68083736; called by muse, mutect2, varscan2
- F13A1 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.19); catalogued as COSV53564199; called by muse, mutect2, varscan2
- GRM3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as rs571579021, COSV64471709, COSV64473083; called by muse, mutect2, varscan2
- HEPHL1 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 81/120 reads (68%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1565360317, COSV59892403; called by muse, mutect2, varscan2
- ITSN1 | c.3376G>A p.G1126S | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV66084913; called by muse, mutect2, varscan2
- KIF20B | c.3598A>G p.N1200D (on ENST00000371728 / NM_001284259.2; = p.N1160D on NM_016195.4) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV53312602; called by muse, mutect2, varscan2
- KRTAP10-3 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 138/214 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs781793784, COSV59973345; called by muse, mutect2, varscan2
- LMX1A | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 31/67 reads (46%) | catalogued as rs1310771479, COSV54225542; called by muse, mutect2, varscan2
- LRP1B | c.10676G>A p.R3559Q | Missense Mutation (SNP) | VAF 101/211 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145915063; called by muse, mutect2, varscan2
- P4HTM | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV59086373; called by muse, mutect2, varscan2
- PGR | c.2437G>T p.V813F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV54807685; called by muse, mutect2, varscan2
- PKHD1 | c.10000A>G p.K3334E | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV61889104; called by muse, mutect2, varscan2
- SMARCA1 | c.2172A>C p.Q724H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV64413186; called by muse, mutect2, varscan2
- TRPV6 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 92/213 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.263); catalogued as rs745408146, COSV63890716; called by muse, mutect2, varscan2
- TUBB4A | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as rs552079378, COSV51152259; called by muse, mutect2, varscan2
- ZYX | c.907T>C p.S303P | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.829); catalogued as COSV59557156; called by muse, mutect2, varscan2
- XK | c.756dup p.W253Lfs*13 | Frame Shift Ins (INS) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- ZNF701 | c.1111_1114del p.K371Ffs*69 (on ENST00000301093; = p.K305Ffs*69 on NM_018260.3) | Frame Shift Del (DEL) | VAF 51/135 reads (38%) | called by mutect2, pindel, varscan2
- NPTX2 | c.1044C>T p.G348= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs756266964, COSV55717138; called by muse, mutect2, varscan2
- NTF3 | c.390G>A p.A130= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV58417644; called by muse, mutect2, varscan2
- PJVK | c.603C>T p.F201= | Silent (SNP) | VAF 95/228 reads (42%) | catalogued as rs762131024, COSV64307003; called by muse, mutect2, varscan2
- TNS4 | c.1848G>A p.T616= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs779189274, COSV54187189; called by muse, mutect2, varscan2
